Gene-level copy-number profile of tumor specimen TCGA-Z2-A8RT-06A from TCGA case TCGA-Z2-A8RT, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; Age at diagnosis: 43.3 years (15,811 days).
Specimen TCGA-Z2-A8RT-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.9e5b9da8-9981-407b-ba00-c84db432bc6f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-Z2-A8RT-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bdaf1ed0-d42e-444f-913d-a5b66164a58d

Most common (modal) total copy number across autosomal genes: 6 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 13; copy number 1: 1; copy number 2: 794; copy number 3: 11,013; copy number 4: 541; copy number 5: 5,995; copy number 6: 38,966; copy number 7: 475; copy number 8: 10; copy number 9: 33; copy number 10: 1,364; copy number 11: 497; copy number 12: 12; copy number 14: 15; copy number 15: 21; copy number 16: 15; copy number 17: 33; copy number 19: 6; copy number 28: 13.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-Z2-A8RT-06A-11D-A371-01): tumor purity 0.83, ploidy 1.82, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:181,064,089–181,835,108, 8 genes: LINC00290, AC019235.1, LINC02500, AC093840.1, AC093840.2, AC084741.1, TEMN3-AS1, RN7SKP13.
- chr4:181,905,790–181,906,467, 1 gene: CCNHP1.
- chr11:81,015,849–81,556,425, 4 genes (within-gene range 0–2): AP003398.2, AP003464.1, MTND4LP18, MTND6P25.

Amplified relative to the modal value (total copy number ≥ 13, i.e. more than twice the modal value of 6; autosomes only): 103 genes in 8 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:16,973,275–17,844,865, 15 genes, copy number 16: AC106894.1, MTND5P4, LINC02493, SNORA75B, RPS7P6, QDPR, CLRN2, NACAP5, AC006160.2, LAP3, AC006160.1, MED28, FAM184B, DCAF16, NCAPG.
- chr4:138,664,725–139,606,699, 26 genes, copy number 17 (within-gene range 9–17): AC098859.2, AC093766.1, AC109927.1, AC109927.2, NOCT, ELF2, RNU6-531P, RN7SL382P, PPP1R14BP3, Metazoa_SRP, RN7SL311P, Y_RNA, RNU6-506P, RNU6-1074P, MGARP, NDUFC1, NAA15, RNU6-1214P, AC097376.3, AC097376.2, AC097376.1, RAB33B, SETD7, FTH1P24, AC112236.2, AC112236.3.
- chr4:139,665,768–140,600,575, 19 genes, copy number 19–28: MGST2, RN7SKP237, H3P16, MAML3, AC108053.1, RN7SKP253, AC131182.1, SCOC, SCOC-AS1, NDUFB4P9, RPL14P3, CLGN, MGAT4D, AC093671.1, ELMOD2, UCP1, AC108019.2, RN7SL152P, AC108019.1.
- chr4:145,599,042–146,243,669, 15 genes, copy number 14: MMAA, NCOA4P3, AC093864.1, C4orf51, ZNF827, AC104791.2, AC104791.1, Y_RNA, AC108206.1, LINC01095, LSM6, AC097372.2, REELD1, AC097372.3, AC097372.1.
- chr4:148,445,703–149,024,624, 1 gene, copy number 17 (within-gene range 11–17): AC002460.2.
- chr4:148,693,032–149,062,522, 6 genes, copy number 17: AC108935.1, ATP5MGP4, AC093648.1, AC002460.1, RNU7-197P, AC108156.1.
- chr4:149,351,709–149,896,233, 1 gene, copy number 15 (within-gene range 4–15): IQCM.
- chr4:149,666,057–151,325,605, 20 genes, copy number 15 (within-gene range 9–15): AC093893.1, AKIRIN2P1, RNA5SP167, RNU6-1230P, AC105343.1, AC105343.2, DCLK2, RNU7-194P, LRBA, AC092612.1, AC110813.1, MAB21L2, ZBTB8OSP1, RNA5SP168, AK4P6, RPS3A, SNORD73B, SH3D19, SNORD73A, AC095055.1.

Autosomal genes at a single copy (total copy number 1): 1. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
